Surgical pathology report (de-identified scan), TCGA case TCGA-DD-AACA, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-AACA-02B (Recurrent Tumor).

[page 1 of 2]
Recurrent 2

CLINICAL DIAGNOSIS: Recurrent HCC

Specimen : liver

Gross Photo :

GROSS:

Specimen status: Fresh

Operation: Partial hepatectomy

Organs: Liver (12.5 x 16.5 x 6.5 cm, 339.5 gm)

Lesion: Multiple liver masses (3.5 x 3.0 x 2.0 cm in maximum dimensions)

Cut surface: variable-sized yellowish tan, solid and firm masses with necrosis

Gross type:

HCC: Vaguely nodular,
Expanding nodular,
Nodular with perinodular extension,
and Infiltrative growth pattern

Resection margin:

Not involved, but very close, grossly (safety margin: 0.1 cm)

Others:

Satellite nodule: Yes

Remaining parenchyma: Cirrhotic change

Representative sections submitted

Gross photo: Present

Blocks

T1-7, mass x 7

L, liver parenchyma x 1

TB, tumor tissue x 1

NB, non-tumor tissue x 1

A, peritoneal mass x 1

MICROSCOPIC:

Hepatocellular carcinoma: Yes

The worst differentiation III

The major differentiation II

Histologic type: Trabecular

Cell type: Hepatic

Fatty change: No

Fibrous capsule formation: Partial capsule

Capsular infiltration: Yes

Septum formation: Yes

Surgical resection margin invasion: No, safety margin (0.1 cm)

Serosal invasion: No

Portal vein invasion: No

Microvessel invasion: Yes

Intrahepatic metastasis: Present

ICD-O-3

Carcinoma, hepatocellular NOS
8170/3

Site Liver C22.0

Op 5/26/14

[page 2 of 2]
Multicentric occurrence: Present

NOT reported. Gross:

NOT reported. Gross:

Liver, ectomy, hepatocellular carcinoma, cirrhosis
Gallbladder, ectomy, cholesterol polyp

Liver, ectomy, hepatocellular carcinoma

Large intestine, sigmoid colon, ectomy, tubular adenoma, low grade, dysplasia

liver,ectomy,Hepatocellular carcinoma,recurrent
T56000, P10, M81703, M80008
lymph node,excision,no tumor
T08000, P12, M09450

DIAGNOSIS:

Liver, partial hepatectomy:

Hepatocellular carcinoma, moderately differentiated, multiple, recurrent
Cirrhosis

Lymph node, labelled as 'peritoneal mass', excision:

No tumor present (0/1)

Suggestion :

Primary received by BCR
Recurrent HCC. #2

Source: NCI Genomic Data Commons file e00e9c00-8b0f-48f5-b51f-80077e1ec7e1 (TCGA-DD-AACA.E3836223-B3ED-46C6-B257-6909E26D0F09.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).